Gene-level copy-number profile of tumor specimen TCGA-AB-2876-03A from TCGA case TCGA-AB-2876, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.6 years (16,648 days).
Specimen TCGA-AB-2876-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.0ca21221-59d8-4e2c-8fdc-3029467c3852.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2876-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/0b6cdd2e-9607-406a-be2f-e948fbea31cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 1,981; copy number 2: 57,290; copy number 3: 469.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:79,025,686–79,185,523, 6 genes: REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1.
- chr2:79,269,905–79,292,878, 1 gene: AC011754.2.
- chr3:21,942,566–21,979,828, 1 gene: ZNF385D-AS2.
- chr8:125,091,679–130,017,129, 68 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:130,069,541–130,084,768, 2 genes: RNU6-1255P, ASAP1-IT2.
- chr8:139,460,062–139,508,971, 2 genes: AC087354.1, AC090093.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,981. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
